Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7481, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7481-01A (Primary Tumor).

Microscopic

Sections demonstrate a glial neoplasm that diffusely infiltrates both gray and white matter. In the gray matter, there is prominent perineuronal satellitosis as well as subpial surface spread. Tumor cells have round nuclei with few apparent cytoplasmic processes. Many demonstrate perinuclear halos. There is little cytologic atypia. No mitotic figures are seen. There is no microvascular proliferation or necrosis.

.

Addendum discussion:

Numerous MIB-1 reactive cells are present throughout the specimen. A labeling index of 21% is calculated. This is indicative of a markedly proliferative glial neoplasm. Despite this, no mitotic figures are identified on the ██████ stain and only a rare mitotic figure was identified on the immunohistochemistry. Consequently, the tumor must be classified as low grade/grade II. Nevertheless, the very high MIB-1 labeling index suggests more aggressive behavior. Close clinical follow-up is indicated.

Final Addendum Diagnosis:

Oligodendroglioma, low grade, WHO grade II

Source: NCI Genomic Data Commons file e87b64bd-8759-467f-95c0-cb5dd26c23aa (TCGA-HT-7481.879A7F04-519F-44C0-BAD3-32C637AB5955.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).